Somatic mutation profile of tumor specimen TCGA-AP-A053-01A (aliquot TCGA-AP-A053-01A-21W-A027-09) from TCGA case TCGA-AP-A053, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-AP-A053-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cc213c6-4206-4dd3-95f9-754ac55ac3b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A053-10A (Blood Derived Normal), aliquot TCGA-AP-A053-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5554e30c-99c7-4c13-8fc7-7798ebca043e

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 3, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 54/114 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 31/39 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATG7 | c.2002G>A p.V668M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV61615794; called by muse, mutect2, varscan2
- BRIP1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs587780227, COSV52000382; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C7orf25 | c.635C>A p.S212* | Nonsense Mutation (SNP) | VAF 29/64 reads (45%) | catalogued as COSV63274385; called by muse, mutect2, varscan2
- CAPN9 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.878); catalogued as COSV55239941; called by muse, mutect2, varscan2
- CCDC190 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV63363318; called by muse, mutect2, varscan2
- CEP170 | c.3461G>T p.R1154L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60515110; called by muse, mutect2, varscan2
- CLPB | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs755613972, COSV53633842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV58596759; called by muse, mutect2, varscan2
- COL3A1 | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV58596766; called by muse, mutect2, varscan2
- EFTUD2 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV68184902; called by muse, mutect2, varscan2
- GPR85 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV51785439; called by muse, mutect2, varscan2
- GSDMA | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 1142/1288 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52859848; called by muse, mutect2, varscan2
- IFNL1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61318360; called by muse, mutect2, varscan2
- IRAG1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV70210449; called by muse, mutect2, varscan2
- KCNC4 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs752369153, COSV63926712; called by muse, mutect2, varscan2
- KIAA1217 | c.5293G>A p.G1765S | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.047); catalogued as rs778072271, COSV56824131; called by muse, mutect2, varscan2
- MAT2B | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs761124437, COSV55202410; called by muse, mutect2, varscan2
- MFSD13A | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.096); catalogued as rs745953305, COSV53269233; called by muse, mutect2, varscan2
- MYCBP2 | c.4041-1G>T p.X1347_splice (on ENST00000357337; = p.X1385_splice on NM_015057.5) | Splice Site (SNP) | VAF 34/79 reads (43%) | catalogued as COSV62039838; called by muse, mutect2, varscan2
- MZT1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1432990874, COSV64698287; called by muse, mutect2, varscan2
- NFATC2 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs752700803, COSV65353297; called by muse, mutect2, varscan2
- NPY5R | c.1235T>A p.L412* | Nonsense Mutation (SNP) | VAF 48/104 reads (46%) | catalogued as COSV58453870; called by muse, mutect2, varscan2
- NSD1 | c.1832G>T p.R611L | Missense Mutation (SNP) | VAF 159/259 reads (61%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV61785020, COSV61785456; called by muse, mutect2, varscan2
- OR5A1 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 154/507 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV57378571; called by muse, mutect2, varscan2
- PABPC5 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 41/70 reads (59%) | catalogued as COSV57040157, COSV57040753; called by muse, mutect2, varscan2
- PEDS1-UBE2V1 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59011655, COSV59016310; called by muse, mutect2, varscan2
- PIGK | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV63063702; called by muse, mutect2, varscan2
- PSEN1 | c.646A>G p.K216E | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56197101; called by muse, mutect2, varscan2
- RASAL1 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV55659922; called by muse, mutect2, varscan2
- SEMA4F | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV60285397; called by muse, mutect2, varscan2
- SLC12A3 | c.2355G>A p.M785I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV52635964; called by muse, mutect2
- SMARCA2 | c.3218G>T p.C1073F | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.986); catalogued as COSV61812881; called by muse, mutect2, varscan2
- SPOCD1 | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV57100242; called by muse, mutect2, varscan2
- TAAR8 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs1288170022, COSV51587295; called by muse, mutect2, varscan2
- TAS2R14 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV67862757; called by muse, mutect2, varscan2
- TEX2 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1212407848, COSV51981561; called by muse, mutect2, varscan2
- TLR10 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 99/117 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58302414; called by muse, mutect2, varscan2
- ZNF791 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58482896; called by muse, mutect2
- CPLANE1 | c.8719_8722del p.R2907Wfs*5 | Frame Shift Del (DEL) | VAF 120/331 reads (36%) | called by pindel, varscan2
- GOLGA6L22 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF17 | c.2604G>A p.E868= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55238433; called by muse, mutect2, varscan2
- CHST1 | c.588G>A p.A196= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV57325828; called by muse, mutect2, varscan2
- ELL | c.1827C>T p.I609= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs780904150, COSV53216030; called by muse, mutect2, varscan2
- KLF10 | c.744G>A p.V248= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV53436882; called by muse, mutect2, varscan2
- OR51A2 | c.555T>C p.D185= | Silent (SNP) | VAF 117/277 reads (42%) | catalogued as COSV100985010, COSV66748803; called by muse, mutect2, varscan2
- OR51A4 | c.555T>C p.D185= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV66750102; called by muse, mutect2, varscan2
- OR52B2 | c.738C>T p.H246= | Silent (SNP) | VAF 72/139 reads (52%) | catalogued as COSV73209644; called by muse, mutect2, varscan2
- PCDHA7 | c.2037G>A p.S679= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV65335666; called by muse, mutect2, varscan2
- PLCH1 | c.1552C>T p.L518= (on ENST00000340059 / NM_001130960.2; = p.L530= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV58210520; called by muse, mutect2
- PPP1R18 | c.1659C>T p.Y553= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV51299203; called by muse, mutect2, varscan2
- CAMK1D | c.1039+21G>A | Intron (SNP) | VAF 141/514 reads (27%) | catalogued as COSV66620002; called by muse, mutect2, varscan2
